Somatic mutation profile of tumor specimen TCGA-D7-A748-01A (aliquot TCGA-D7-A748-01A-12D-A32N-08) from TCGA case TCGA-D7-A748, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 41.6 years (15,190 days).
Specimen TCGA-D7-A748-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6387287-0b68-4226-b5be-679af5da73c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-A748-10A (Blood Derived Normal), aliquot TCGA-D7-A748-10A-21D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b7dd80b-3bb0-477a-878a-6dcaf4f05638

The open-access MAF lists 39 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 8, Nonsense Mutation 3, Splice Site 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TGFBR1 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 7/67 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs113605875, CM050757, CM063198, COSV66625173; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALG10B | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 23/349 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.683); catalogued as COSV100439931; called by muse, mutect2
- AQP5 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52230869, COSV99527496; called by muse, mutect2, varscan2
- ATP1A3 | c.1297C>T p.R433C (on ENST00000545399 / NM_001256214.2; = p.R420C on NM_152296.5) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1318364500, COSV57491023; called by muse, mutect2
- C12orf42 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs1251170925, COSV59382366; called by muse, mutect2
- CDH1 | c.1009-2A>G p.X337_splice | Splice Site (SNP) | VAF 27/112 reads (24%) | catalogued as COSV55743415, COSV99931068; called by muse, mutect2, varscan2
- CDH9 | c.1165T>G p.L389V | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as COSV50339154, COSV99145991; called by muse, mutect2
- CEP170B | c.4381A>G p.I1461V (on ENST00000453495; = p.I1390V on NM_015005.3) | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.024); catalogued as COSV99229835; called by muse, mutect2, varscan2
- CFAP91 | c.1823G>A p.R608Q | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1007945476, COSV56340117; called by muse, mutect2
- DLG1 | c.1541C>A p.S514* | Nonsense Mutation (SNP) | VAF 10/98 reads (10%) | catalogued as COSV100015522; called by muse, mutect2, varscan2
- GABRA4 | c.1612T>G p.W538G | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99974227; called by muse, mutect2
- GRIK5 | c.968G>T p.R323L | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1004509650, COSV99490797; called by muse, mutect2
- IQSEC1 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs376868528; called by muse, mutect2, varscan2
- IRF2BP2 | c.1616A>G p.K539R | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV100784341; called by muse, mutect2
- MAP2K7 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769642939, COSV67607958; called by muse, mutect2
- MARCO | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | catalogued as COSV100503603, COSV59052677; called by mutect2, varscan2
- NARS2 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 15/195 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757944504, COSV99807306; called by muse, mutect2
- NEK10 | c.3173G>T p.R1058I | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55366027; called by muse, mutect2
- OR51A7 | c.645G>C p.L215F | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV100834691; called by muse, mutect2
- OR8G5 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.054); catalogued as rs768959879, COSV100422509; called by muse, mutect2
- PCDHB13 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53400139; called by muse, mutect2, varscan2
- PCDHB16 | c.1211T>A p.V404E | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.394); catalogued as COSV99502277; called by muse, mutect2
- PCDHB4 | c.951A>C p.E317D | Missense Mutation (SNP) | VAF 13/269 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs1554274445, COSV99522307; called by muse, mutect2
- RAB8A | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.268); catalogued as COSV99959833; called by muse, mutect2, varscan2
- SF3A1 | c.1414C>T p.R472W | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53167577; called by muse, mutect2
- SLC6A15 | c.1820C>A p.A607E | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99881087; called by muse, mutect2
- SPEN | c.3793C>T p.R1265* | Nonsense Mutation (SNP) | VAF 6/143 reads (4%) | catalogued as COSV65357409; called by muse, mutect2
- TBC1D9 | c.1598A>G p.N533S | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.673); catalogued as rs766985680, COSV101464364; called by muse, mutect2, varscan2
- TMF1 | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 33/294 reads (11%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as COSV101275444; called by muse, mutect2, varscan2
- ITIH6 | c.3673del p.L1225Wfs*18 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel
- ANKEF1 | c.627T>G p.G209= | Silent (SNP) | VAF 17/176 reads (10%) | catalogued as COSV101001043; called by muse, mutect2
- CECR2 | c.2811G>A p.P937= (on ENST00000342247 / NM_001290047.2; = p.P754= on NM_001290046.1) | Silent (SNP) | VAF 15/170 reads (9%) | catalogued as rs772645934, COSV99378341; called by muse, mutect2
- L1CAM | c.603C>T p.S201= | Silent (SNP) | VAF 12/168 reads (7%) | catalogued as rs782223025, COSV62828583; ClinVar: uncertain significance; called by muse, mutect2
- NDST1 | c.834C>T p.R278= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as rs376056556; ClinVar: likely benign; called by muse, mutect2, varscan2
- PAPSS2 | c.978T>C p.A326= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV100753589; called by muse, mutect2, varscan2
- SSX5 | c.15T>C p.D5= | Silent (SNP) | VAF 30/266 reads (11%) | catalogued as COSV100308802; called by muse, mutect2, varscan2
- TAOK3 | c.2487G>A p.Q829= | Silent (SNP) | VAF 7/96 reads (7%) | catalogued as COSV101183595; called by muse, mutect2
- VWA2 | c.2070T>G p.A690= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV100073786; called by mutect2, varscan2
- LAMP2 | c.1093+2550A>C | Intron (SNP) | VAF 18/132 reads (14%) | catalogued as COSV99568580; called by muse, mutect2, varscan2
